Surgical pathology report (de-identified scan), TCGA case TCGA-HW-A5KK, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-A5KK-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT
*** Addendum ***

Patient Name:

Med. Rec. #:

DOB:

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right temporal lobe brain lesion.

Specimens Submitted:

- 1: Right medial medial temporal lesion (fs)
- 2: Right medial temporal lobe brain lesion
- 3: Right temporal lobe brain lesion

DIAGNOSIS:

1. Right medial medial temporal lesion; biopsy (fs):
- Astrocytoma, see part 3 below.
2. Right medial temporal lobe brain lesion; biopsy:
- Astrocytoma, see part 3 below.
3. Right temporal lobe brain lesion:
TUMOR TYPE:
Anaplastic astrocytoma
WHO GRADE:
III

ICD-O-3
Astrocytoma, anaplastic 94013
Site Path ^Q Brain, temporal lobe
C71.2
C71.0
C71.0
94011/18/13
NAS

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain

Comment

VIMEN
IMM RECUT
NEG CONT
IDH1-H09
VIMEN
IDH1-H09

Gross Description:

[page 2 of 3]
1. The specimen is received fresh for frozen section consultation labeled "Right medial temporal lesion" and consists of a yellow soft tissue measuring 0.6 x 0.5 x 0.2 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

FSCA: frozen section control

2) The specimen is received fresh labeled, "right medial temporal lobe brain lesion", and consists of multiple pieces of gray tan friable soft tissue measuring 1.3 x 0.7 x 0.3 cm in aggregate. The specimen is entirely submitted.

Summary of sections:

U - undesignated

3) The specimen is received fresh labeled, "right temporal lobe brain lesion", and consists of multiple large portions of gray tan soft tissue measuring 5.4 x 5.0 x 2.0 cm in aggregate. A sample is submitted to TPS. The remainder of the specimen is approximately 50%.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Right medial temporal lesion (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: Right medial temporal lobe brain lesion

Block	Sect. Site	PCs
1		1

Part 3: Right temporal lobe brain lesion

Block	Sect. Site	PCs
6	U	3

Procedures/Addenda:

Addendum

Date Ordered:

Status:

Date Complete:

Date Reported:

Addendum Diagnosis

Immunostudies reveal that the tumor cells are negative for R132H mutant IDH. There is loss of PTEN expression.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

[page 3 of 3]
*** Report Electronically Signed Out ***

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Astrocytoma, favor high grade
PERMANENT DIAGNOSIS: Same

Cellular Discrepancy		

Source: NCI Genomic Data Commons file 5f0cf2fa-1c1e-4941-a6ea-40f48f439270 (TCGA-HW-A5KK.3F8E4F24-CEB2-4B96-B251-DC0C2B8A6205.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).